Surgical pathology report (de-identified scan), TCGA case TCGA-QR-A6GT, project TCGA-PCPG (Pheochromocytoma and Paraganglioma), tissue source site National Institutes of Health, specimen TCGA-QR-A6GT-01A (Primary Tumor).

[page 1 of 3]
Final Results

Surgical Pathology

Final

CASE NUMBER:

DIAGNOSIS:

1. SOFT TISSUE, PERITONEUM, "NODULE ANTERIOR TO LEFT RENAL VEIN" (EXCISION): LOOSE FIBROCONNECTIVE TISSUE AND FRAGMENTS OF ADIPOSE TISSUE.
2. LYMPH NODE, AORTOCAVAL, "BELOW RENAL VEIN" (EXCISION): HYPERPLASTIC LYMPH NODE WITH VASCULAR MEDULLARY ACCENTUATION.
3. LYMPH NODE, AORTOCAVAL (EXCISION): BENIGN LYMPH NODE.

4. KIDNEY AND ADRENAL GLAND, RIGHT (RADICAL NEPHRECTOMY): PERIRENAL MASS CONSISTENT WITH PHEOCHROMOCYTOMA MEASURING 10 X 5 X 5 CM; THE TUMOR MASS IS ADJACENT TO BUT NOT INVOLVING THE ADRENAL GLAND. DIAGNOSTIC FEATURES SUGGESTIVE OF MALIGNANT PHEOCHROMOCYTOMA INCLUDE TUMOR SIZE, TUMOR PERFORATION INTO THE RENAL VEIN (BLOCK 4C), AND FAINT TO ABSENT STAINING FOR S-100, SEE NOTE.

NOTE: IMMUNOHISTOCHEMICAL STUDIES WERE PERFORMED. NEOPLASTIC CELLS ARE NEGATIVE FOR AE1/3, CAM5.2, HMB-45, AND MART-1. NEOPLASTIC CELLS ARE POSITIVE FOR SYNAPTOPHYSIN, CHROMOGRANIN, MELAN A, AND INHIBIN. S-100 STAINS RETICULOENDOTHELIAL CELLS WITHOUT A SUSTENTACULAR PATTERN, WHILE NEOPLASTIC CELLS ARE NEGATIVE FOR THIS MARKER. INHIBIN AND MELAN A POSITIVITY IN THIS NEOPLASM ARE APPARENTLY DISPARATE STAINING RESULTS BECAUSE PHEOCHROMOCYTOMAS HAVE NOT ORDINARILY BEEN REPORTED IN THE LITERATURE TO BE POSITIVE FOR THEM. HOWEVER, WE PLACE MORE EMPHASIS ON THE CHROMOGRANIN RESULT WHICH CLEARLY IS NEGATIVE IN THE PATIENT'S OWN ADRENAL CORTEX, BUT POSITIVE IN THE PATIENT'S ADRENAL MEDULLA AND TUMOR. THIS FINDING ALONE POINTS STRONGLY TO PHEOCHROMOCYTOMA. BECAUSE OF POTENTIAL FOR MALIGNANCY, CONTINUING CLINICAL EVALUATION FOR BONE METASTASES IS RECOMMENDED.

CLINICAL INFORMATION: HISTORY: RETROPERITONEAL MASS, CLINICAL PHEO EXAM IS RELATED TO ORDERING PROTOCOL ORDERING PROTOCOL:

PROCEDURE: PREOP DX: #PHEOCHROMOCYTOMA POSTOP DX: PHEO OPERATIVE FINDINGS: LARGE RETROPERITONEAL MASS, KIDNEY HILUM, URETER ENCASED

SPECIMENS SUBMITTED: 1) PERITONEAL BIOPSY, NODULE ANTERIOR TO LT VEIN (1FS) 2) LYMPH NODES, INTERAORTIC CAVAL BELOW RENAL VEIN (2FS) 3) LYMPH NODES, INTRA AORTIC CAVAL (3FS) 4) ADRENAL GLAND, RIGHT, AND KIDNEY

INTRAOPERATIVE CONSULTATION:

1FS DIAGNOSIS: FIBROADIPOSE TISSUE WITH FOCAL FAT NECROSIS, NO TUMOR SEEN (DRS.

2FS DIAGNOSIS: LYMPH NODE AND FAT, NO TUMOR SEEN (DRS.

3FS DIAGNOSIS: LYMPH NODE, NO TUMOR SEEN (ONLY ONE FROZEN SECTION PERFORMED DUE TO EXHAUSTION OF BLOCK)

Requested By:

Do not file in Medical Record

[page 2 of 3]
GROSS DESCRIPTION:

RECEIVED FRESH FROM THE OPERATING ROOM ARE 4 CONTAINERS LABELED WITH THE PATIENT'S NAME AND MEDICAL RECORD NUMBER.

1. SPECIMEN 1 IS LABELED "PERITONEAL NODULE ANTERIOR TO LEFT RENAL VEIN. THE SPECIMEN CONSISTS OF TAN/RED, FLOCCULENT TISSUE, MEASURING 0.3 X 0.2 X 0.2 CM. THE SPECIMEN IS FROZEN IN TOTO AS 1FS. THE FROZEN SECTION CONTROL IS RECEIVED BY MYSELF IN FORMALIN AND TRANSFERRED FROM A SINGLE GREEN CASSETTE LABELED WITH THE PATIENT'S NAME AND 1FS1 TO A SINGLE ORANGE CASSETTE LABELED 1FS.

2. SPECIMEN 2 IS LABELED "INTRA AORTIC CAVAL NODE BELOW RENAL VEIN". THE SPECIMEN CONSISTS OF A 4.5 X 2.5 X 0.5 CM. FRAGMENT OF FATTY TISSUE WITHIN WHICH THERE IS A 1.3 X 0.8 X 0.4 CM. LYMPH NODE. THE LYMPH NODE SPECIMEN IS FROZEN AS 2FS1. A TOUCH PREP IS LABELED 2TP. THE FROZEN SECTION CONTROL IS RECEIVED BY MYSELF IN FORMALIN AND TRANSFERRED FROM A GREEN CASSETTE LABELED WITH THE PATIENT'S NAME AND 2FS1 TO A SINGLE ORANGE CASSETTE LABELED 2FS. THE REMAINING UNFROZEN TISSUE IS BISECTED AND ENTIRELY SUBMITTED IN TWO WHITE CASSETTES LABELED 2A AND B.

3. SPECIMEN 3 IS LABELED "INTERAORTOCAVAL NODE". THE SPECIMEN CONSISTS OF A SINGLE FRAGMENT OF FATTY TISSUE MEASURING 2 X 1.8 X 0.6 CM. WITH A STAPLE AND A LYMPH NODE, MEASURING 0.8 X 0.6 X 0.3 CM. THE LYMPH NODE IS BISECTED AND FROZEN IN TOTO AS 3FS1. THE FROZEN SECTION CONTROL IS RECEIVED BY MYSELF IN FORMALIN AND TRANSFERRED FROM A GREEN CASSETTE LABELED WITH THE PATIENT'S NAME AND 3FS TO A SINGLE ORANGE CASSETTE LABELED 3FS. THE RESIDUAL UNFROZEN PORTION OF TISSUE IS BISECTED AND ENTIRELY SUBMITTED IN WHITE CASSETTE LABELED #3.

4. SPECIMEN 4 IS LABELED "RIGHT ADRENAL AND KIDNEY". THE SPECIMEN CONSISTS OF A 431 GRAM KIDNEY AND ADRENAL MEASURING 15 X 12 X 6 CM. THERE IS A TUMOR ABUTTING THE ADRENAL GLAND MEASURING 10 X 5 X 5 CM. THE TUMOR IS YELLOW AND NECROTIC ON CUT SURFACE. 2 X 2 X 2 CM. OF TUMOR ARE PROCURED BY THE UROLOGIC ONCOLOGY BRANCH AS WELL AS 2 X 1 X 1 CM. OF NORMAL KIDNEY AND 1 X 0.5 X 0.5 CM. OF NORMAL ADRENAL. THE PREVIOUS DESCRIPTION WAS PROVIDED BY DR. THE SPECIMEN IS RECEIVED BY MYSELF AND MEETS THE ABOVE DESCRIPTION. AS MENTIONED, THE TUMOR IS MULTINODULAR AND YELLOWISH/TAN IN COLOR WITH FOCAL DARK BROWN TO PURPLISH/BLACK AREAS. IN PLACES, THERE IS APPARENT NECROSIS AND IN OTHERS THERE IS TRANSLUCENT, MYXOID- APPEARING, CENTRAL STROMA. THERE IS NO GROSS EVIDENCE OF DIRECT INVOLVEMENT OF THE KIDNEY PARENCHYMA, BUT RATHER THE KIDNEY APPEARS EXTERNALLY COMPRESSED BY THIS MASS. RESIDUAL NORMAL ADRENAL IS IDENTIFIED IN THE SUPERIOR POLE OF THE SPECIMEN AND THERE ARE MASSES OF APPARENT TUMOR NODULE ADJACENT TO THESE AREAS OF APPARENT NORMAL ADRENAL. THE RENAL HILUM IS DISTORTED BY THE PRESENCE OF THE LARGE TUMOR MASS. CLIPS ARE IDENTIFIED ON VASCULAR STRUCTURES SURROUNDING THE TUMOR AND THE HILUM AND THE CUT SURFACES OF THE VASCULAR STRUCTURES ARE TAKEN AS MARGINAL SECTIONS. IN ADDITION, THE URETER IS IDENTIFIED AND THE CUT MARGIN TAKEN. APPROXIMATELY A 6 CM. PORTION OF URETER REMAINS. ALSO AT THE HILUM IS AN OPENED LUMINAL SPACE WHICH MAY REPRESENT PORTIONS OF THE RENAL VEIN, NOT ENTIRELY CONTIGUOUS TO THE MORE DISTAL MARGIN WHICH WAS PREVIOUSLY IDENTIFIED. THIS WAS DISCUSSED WITH THE PROCUREMENT TEAM AND THIS DISCONTINUITY WAS PRESENT AT TIME OF PROCUREMENT. IT IS ALSO POSSIBLE THAT THIS COULD REPRESENT A DISTAL DILATATION OF THE CALYCEAL SYSTEM. WITHIN THIS STRUCTURE ARE SEVERAL TAN-COLORED EXCRESCENCES INTO THE LUMEN MEASURING 0.3 CM. IN GREATEST DIMENSION. NO OBVIOUS HILAR LYMPH NODES ARE IDENTIFIED. SECTIONS ARE SUBMITTED AS FOLLOWS:

4A: VASCULAR AND URETERAL MARGINS

4B: STRUCTURE AT HILUM, POSSIBLE RENAL VEIN OR DILATED PELVIS

Requested By:

Do not file in Medical Record

[page 3 of 3]
Final Results

4C: AND 4D: LUMINAL STRUCTURE AT PELVIS WITHIN INTRALUMINAL NODULAR EXCRESCENCES
4E THROUGH 4H: APPARENT TUMOR ADJACENT TO GROSSLY UNREMARKABLE ADRENAL
4I THROUGH 4M: TUMOR WITH OVERLYING GREEN INKED MARGINAL SURFACE.
4N AND 4O: RELATIONSHIP OF TUMOR TO RENAL PELVIS
4P THROUGH 4R: TUMOR ADJACENT TO NORMAL-APPEARING RENAL PARENCHYMA
4S: NORMAL-APPEARING RENAL PARENCHYMA
4T: ADDITIONAL TUMOR ADJACENT TO GREEN INKED OVERLYING MARGIN
4U AND 4V: TUMOR, CENTRAL TRANSLUCENT AREA
4W: TUMOR WITH DARK BROWN NODULE AND PALE, TRANSLUCENT NODULAR AREA AND OTHER
NECROTIC-APPEARING AREA
REVIEWED BY: SURGICAL PATH CASE CONF,

Requested By

Do not file in Medical Record

Histologic Discrepancy		
Reviewer Initials	Date Re-viewed: 5/22/13	

Source: NCI Genomic Data Commons file 8402a361-81fd-48a2-9d6a-274d6da923ed (TCGA-QR-A6GT.ECF9DE13-4F2B-4BFA-A560-D7D8AB3146B4.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).